Somatic mutation profile of tumor specimen TCGA-A2-A0EQ-01A (aliquot TCGA-A2-A0EQ-01A-11W-A050-09) from TCGA case TCGA-A2-A0EQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.5 years (23,543 days).
Specimen TCGA-A2-A0EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6378cdee-6e32-41b2-8791-b2dea3ba8ab0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0EQ-10A (Blood Derived Normal), aliquot TCGA-A2-A0EQ-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae76e7e9-ea0a-4917-b1dc-781bf16a4d17

The open-access MAF lists 235 somatic variants for this specimen: 168 protein-altering or splice-affecting, 65 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 65, Nonsense Mutation 7, Splice Site 4, Splice Region 1, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 36/111 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.485_487del p.I162_Y163delinsN | In Frame Del (DEL) | VAF 54/208 reads (26%) | hotspot (GDC flag); catalogued as COSV52762796; called by mutect2, pindel, varscan2
- ABCA5 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as COSV101201289; called by muse, mutect2
- ABI3BP | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); catalogued as COSV99428645; called by muse, mutect2
- ABLIM1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV99522749; called by muse, mutect2
- ACSS3 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54085318; called by muse, mutect2
- ACVR2A | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54019572; called by muse, mutect2, varscan2
- ADCY8 | c.1490G>T p.R497L | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53897935, COSV99654522; called by muse, mutect2, varscan2
- ADGRB1 | c.1318dup p.Q440Pfs*8 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | catalogued as rs772974645; called by mutect2, varscan2
- AFTPH | c.2787C>G p.S929R (on ENST00000238855 / NM_203437.3; = p.S902R on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99481255; called by muse, mutect2
- ANKRD28 | c.1851G>C p.K617N | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV101080953, COSV101081015; called by muse, mutect2
- AOX1 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV101022242; called by muse, mutect2
- APLF | c.1285A>C p.R429= | Splice Region (SNP) | VAF 15/280 reads (5%) | catalogued as COSV100377061; called by muse, mutect2
- ARID5B | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.195); catalogued as COSV99690476; called by muse, mutect2
- BAP1 | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56231244; called by muse, mutect2, varscan2
- BRDT | c.2371C>G p.Q791E | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV100746599; called by muse, mutect2
- C14orf93 | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs1253435160, COSV100136825; called by muse, mutect2
- C19orf54 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.547); catalogued as COSV54573480; called by muse, mutect2, varscan2
- CATSPERE | c.1855C>G p.L619V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.509); catalogued as COSV63676377; called by muse, mutect2, varscan2
- CCDC90B | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs762292538, COSV99475439; called by muse, mutect2
- CDK17 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV54128157, COSV99703107; called by muse, mutect2
- CELA1 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV53329079; called by muse, mutect2, varscan2
- CELF6 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54715464; called by muse, mutect2, varscan2
- CEP350 | c.6331G>C p.D2111H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1398225480, COSV104423753; called by muse, mutect2
- CEP89 | c.1252G>C p.V418L | Missense Mutation (SNP) | VAF 27/666 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV99994023; called by muse, mutect2
- CHRNA10 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV51703069, COSV99167270; called by muse, mutect2, varscan2
- CNGB3 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 31/645 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs368249894, CM136015; called by muse, mutect2
- CNOT6L | c.388C>G p.L130V (on ENST00000504123 / NM_001286790.2; = p.L125V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99362229; called by muse, mutect2
- COL12A1 | c.6136G>A p.D2046N | Missense Mutation (SNP) | VAF 62/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1350175616, COSV100486584; called by muse, mutect2, varscan2
- COL26A1 | c.311G>C p.R104T (on ENST00000313669 / NM_001278563.3; = p.R102T on NM_133457.4) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV58120941; called by muse, mutect2, varscan2
- COPG2 | c.234A>C p.Q78H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447025056, COSV58404282; called by muse, mutect2, varscan2
- CSTF1 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99410357; called by muse, mutect2
- DAB2IP | c.3471G>C p.E1157D (on ENST00000408936; = p.E1129D on NM_032552.3) | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99406390; called by muse, mutect2
- DACH2 | c.1170G>C p.Q390H | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV100913957, COSV64188282; called by muse, mutect2
- DHRS9 | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100513706; called by muse, mutect2
- DNAH3 | c.2970-1G>C p.X990_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99770735; called by muse, mutect2
- DNAH5 | c.5639C>T p.S1880F | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54243093; called by muse, mutect2
- DNAJB7 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV53420992; called by muse, mutect2, varscan2
- DOCK5 | c.3478G>C p.E1160Q | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99377973; called by muse, mutect2
- DYRK1A | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV58292588; called by muse, mutect2, varscan2
- DYRK1A | c.1744C>G p.H582D | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV100118320; called by muse, mutect2
- E2F8 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as COSV51462162, COSV51465254; called by muse, mutect2, varscan2
- ELOVL4 | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876424; called by muse, mutect2
- ENTPD7 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV100978496, COSV65111991; called by muse, mutect2
- EPB41L1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 45/194 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV52434443; called by muse, mutect2, varscan2
- FAM184A | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as COSV100138386; called by muse, mutect2
- FARSB | c.787-1G>A p.X263_splice | Splice Site (SNP) | VAF 20/117 reads (17%) | catalogued as COSV99918692; called by muse, mutect2
- FAT4 | c.1218C>G p.H406Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV67881268, COSV67882033; called by muse, mutect2, varscan2
- FLG | c.10762C>T p.H3588Y | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100912244; called by muse, mutect2
- FNDC1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 96/376 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51931917; called by muse, mutect2, varscan2
- FRMD5 | c.1639C>G p.Q547E | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101296400, COSV68720556; called by muse, mutect2, varscan2
- FRS2 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV100166389, COSV54725009; called by muse, mutect2
- GBP7 | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV54008333; called by muse, varscan2
- GGT7 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs556288098, COSV100321660, COSV100322221; called by muse, mutect2
- GMPR | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV99440594; called by muse, mutect2
- GPC5 | c.852C>A p.H284Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV65580522; called by muse, mutect2, varscan2
- GTF2F2 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV100477451; called by muse, mutect2
- GTF3C4 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV100936098; called by muse, mutect2
- GUCY2C | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53786584, COSV53786766; called by muse, mutect2, varscan2
- H3C7 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV55099930; called by muse, mutect2
- HNRNPH3 | c.1040G>C p.*347Sext*32 | Nonstop Mutation (SNP) | VAF 25/395 reads (6%) | catalogued as COSV56260433; called by muse, mutect2
- HSPA12A | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV100979964; called by muse, mutect2
- ICE1 | c.1897T>C p.S633P | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV56832078; called by muse, mutect2
- IGHV3-38 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); catalogued as rs1229755096; called by muse, mutect2, varscan2
- INPP5F | c.2987C>A p.S996* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | catalogued as COSV100740401; called by muse, mutect2
- INPPL1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.76); catalogued as COSV99996670; called by muse, mutect2
- INTS6 | c.2059A>G p.T687A | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100247277; called by muse, mutect2
- ITPKB | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs777749333, COSV55257873; called by muse, varscan2
- KIF20A | c.2277G>C p.E759D | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV101203152; called by muse, mutect2
- KRTAP10-11 | c.219C>G p.S73R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100555556; called by muse, mutect2
- KRTAP19-1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV101185876, COSV66861531; called by muse, mutect2
- LONRF3 | c.1214C>A p.S405Y (on ENST00000371628 / NM_001031855.3; = p.S364Y on NM_024778.5) | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100504703; called by muse, mutect2
- LPIN2 | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99598924; called by muse, mutect2
- LRP1B | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV101261387; called by muse, mutect2
- MAGEL2 | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs1433677205, COSV58566058, COSV99041383; called by muse, mutect2, varscan2
- MCAT | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs139167631; called by muse, mutect2, varscan2
- MCM10 | c.835C>G p.Q279E (on ENST00000484800 / NM_182751.3; = p.Q278E on NM_018518.5) | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV101098463; called by muse, mutect2
- MCTP2 | c.2075T>C p.I692T | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV59141359; called by muse, mutect2, varscan2
- MOV10L1 | c.1308C>G p.F436L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV53176405, COSV99435210; called by mutect2, varscan2
- MPDZ | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as COSV59915730; called by muse, mutect2, varscan2
- MPO | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99833040; called by muse, mutect2
- MRPS22 | c.805G>C p.G269R (on ENST00000310776 / NM_001363893.1; = p.G270R on NM_020191.4) | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60349220; called by muse, mutect2, varscan2
- MTIF2 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs1391584407, COSV99709363; called by muse, mutect2
- MUC16 | c.42348G>C p.K14116N | Missense Mutation (SNP) | VAF 22/709 reads (3%) | SIFT tolerated, low confidence (0.68); PolyPhen probably damaging (0.974); catalogued as COSV101110096; called by muse, mutect2
- MUC20 | c.1897A>G p.K633E | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV57847925; called by muse, mutect2, varscan2
- MYH9 | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99339875; called by muse, mutect2
- MYO18A | c.4507G>C p.E1503Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.099); catalogued as COSV100572757, COSV62871346; called by muse, mutect2
- NAA11 | c.528G>C p.E176D | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV54514299, COSV99727613; called by muse, mutect2
- NCKAP5 | c.4900G>A p.E1634K | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV100494504, COSV58479329; called by muse, mutect2
- NKAPL | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59197099; called by muse, mutect2, varscan2
- NR4A2 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59892749; called by muse, mutect2, varscan2
- NUP54 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1223059184, COSV99345499; called by muse, mutect2
- OR2AK2 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63564981; called by muse, mutect2
- OR5B21 | c.696G>C p.K232N | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as COSV100835188; called by muse, mutect2
- OR6X1 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60009434; called by muse, mutect2, varscan2
- OTOF | c.4161G>C p.Q1387H (on ENST00000272371 / NM_194248.3; = p.Q620H on NM_004802.4) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as COSV55497119; called by muse, mutect2, varscan2
- OTOGL | c.4236G>C p.M1412I (on ENST00000547103; = p.M1403I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101509513; called by muse, mutect2
- P4HA1 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs775043819, COSV99697241; called by muse, mutect2
- PAMR1 | c.1737C>G p.I579M (on ENST00000619888 / NM_001001991.3; = p.I596M on NM_015430.4) | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53510116; called by muse, mutect2, varscan2
- PBX3 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100655596; called by muse, mutect2
- PDXDC1 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 7/104 reads (7%) | catalogued as COSV55076194; called by muse, mutect2
- PHF20L1 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 18/318 reads (6%) | catalogued as COSV55188987; called by muse, mutect2
- PITPNM1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV62707527, COSV62709897; called by muse, varscan2
- PKD1L1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV56958986; called by muse, mutect2, varscan2
- PPP3CA | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV59920146; called by muse, mutect2, varscan2
- PRDM2 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99342746; called by muse, mutect2
- PRDM5 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV99310616, COSV99311455; called by muse, mutect2
- PREPL | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV99576509; called by muse, mutect2
- PRKDC | c.5395G>T p.E1799* | Nonsense Mutation (SNP) | VAF 8/193 reads (4%) | catalogued as COSV100042979; called by muse, mutect2
- PRUNE2 | c.6274C>T p.H2092Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100945177; called by muse, mutect2
- PSMA3 | c.477+1G>A p.X159_splice | Splice Site (SNP) | VAF 39/266 reads (15%) | catalogued as rs1267951888, COSV53616442; called by muse, mutect2, varscan2
- PSMC5 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99856658; called by muse, mutect2
- QRICH1 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100455189; called by muse, mutect2, varscan2
- RAD54B | c.2509C>G p.H837D | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100280232; called by muse, mutect2
- RANBP2 | c.2421G>C p.Q807H | Missense Mutation (SNP) | VAF 77/418 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV51697103; called by muse, mutect2, varscan2
- RASSF4 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100436832, COSV100437274; called by muse, mutect2
- RIMBP2 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV99900573; called by muse, mutect2
- RNF43 | c.1274C>G p.S425* | Nonsense Mutation (SNP) | VAF 14/192 reads (7%) | catalogued as COSV101348592; called by muse, mutect2
- ROBO3 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as COSV67300582, COSV67301322; called by muse, mutect2
- RPGRIP1 | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99251951; called by muse, mutect2
- RSPH4A | c.1405C>G p.P469A | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV57633818; called by muse, mutect2, varscan2
- RYR2 | c.2608A>T p.S870C | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100772986; called by muse, mutect2
- RYR3 | c.14481G>C p.L4827F (on ENST00000389232; = p.L4828F on NM_001036.6) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60732449; called by muse, mutect2, varscan2
- SCAPER | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100239617; called by muse, mutect2
- SEPSECS | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100259042, COSV57207347; called by muse, mutect2
- SERPINF1 | c.858G>C p.L286F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV99628986; called by muse, mutect2
- SHPRH | c.4103G>A p.R1368K (on ENST00000275233 / NM_001042683.3; = p.R1372K on NM_173082.3) | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1444067953; called by muse, mutect2
- SIX1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1445078561, COSV99903504; called by muse, mutect2
- SLC18B1 | c.1135C>T p.L379F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV99259353; called by muse, mutect2
- SLC25A18 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs140365489, COSV53657156; called by muse, mutect2, varscan2
- SLC4A3 | c.3265G>C p.A1089P | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99813252; called by muse, mutect2
- SMARCA4 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60788162; called by muse, mutect2, varscan2
- SMC1B | c.1781T>C p.V594A | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs750340580, COSV62528474; called by muse, mutect2, varscan2
- SNAPC1 | c.1073-1G>C p.X358_splice | Splice Site (SNP) | VAF 16/196 reads (8%) | catalogued as COSV99359431; called by muse, mutect2
- SPATA31D1 | c.1084C>G p.H362D | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV100783065; called by muse, mutect2
- STAG2 | c.2093A>G p.H698R | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1332603144, COSV54351958; called by muse, mutect2, varscan2
- STAT5B | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs199894785; called by muse, mutect2, varscan2
- STXBP6 | c.501G>C p.Q167H | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV100122234; called by muse, mutect2
- SWAP70 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.079); catalogued as COSV100014148; called by muse, mutect2
- SYNE2 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100648520; called by muse, mutect2, varscan2
- TENM3 | c.5812G>T p.A1938S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV101305483; called by muse, mutect2
- TLK1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100688856; called by muse, mutect2
- TMCO4 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as COSV99230491; called by muse, mutect2
- TMEM67 | c.2375G>T p.R792I | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100019925; called by muse, mutect2
- TP53INP1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 10/334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711147; called by muse, mutect2
- TRDN | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100523446; called by muse, mutect2
- TRDV1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV101153569; called by muse, mutect2
- TRERF1 | c.1663C>G p.Q555E | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV100551755; called by muse, mutect2
- TRIM38 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV62641747; called by muse, mutect2, varscan2
- TRIM60 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV61971792; called by muse, mutect2
- TRIM68 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100331829, COSV56170555; called by muse, mutect2
- TTLL5 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54028776, COSV54037759; called by muse, mutect2, varscan2
- TUBB4B | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61115672; called by muse, mutect2
- UBR2 | c.574T>C p.Y192H | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV65767389; called by muse, mutect2, varscan2
- WDR7 | c.1597A>G p.I533V | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs778537690, COSV54348925; called by mutect2, varscan2
- ZFHX4 | c.10619C>T p.S3540F | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99267998; called by muse, mutect2
- ZNF208 | c.2696G>T p.S899I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs986677091, COSV101237212; called by muse, mutect2
- ZNF217 | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs367766581, COSV56594474; called by muse, mutect2, varscan2
- ZNF233 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100492480; called by muse, mutect2
- ZNF479 | c.1447C>A p.H483N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV58636327; called by muse, mutect2, varscan2
- ZNF674 | c.1539C>G p.I513M | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1467163795, COSV70378648, COSV70379887; called by muse, mutect2, varscan2
- ZNF674 | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70378651; called by muse, mutect2, varscan2
- ZSCAN5B | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 49/850 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100748552, COSV62838810; called by muse, mutect2
- DOCK3 | c.76del p.V26Sfs*2 | Frame Shift Del (DEL) | VAF 86/344 reads (25%) | called by mutect2, pindel, varscan2
- MMRN2 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2
- NCKIPSD | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- PRR12 | c.2930G>T p.R977M (on ENST00000615927; = p.R1798M on NM_020719.3) | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- RNF114 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 5/127 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ABCA13 | c.9018T>G p.L3006= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV71284050; called by muse, mutect2, varscan2
- ANAPC5 | c.1830C>G p.L610= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as COSV99946505; called by muse, mutect2
- ANKRD46 | c.252C>T p.L84= | Silent (SNP) | VAF 7/190 reads (4%) | catalogued as rs1217408862, COSV59514353; called by muse, mutect2
- C1S | c.1488G>A p.R496= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV100196785, COSV61072131; called by muse, mutect2
- C9 | c.1284C>G p.L428= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as COSV99662579; called by muse, mutect2
- CADPS2 | c.1095C>T p.F365= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV100466055; called by muse, mutect2
- CARMIL1 | c.702C>T p.V234= | Silent (SNP) | VAF 43/344 reads (13%) | catalogued as COSV61514330; called by muse, mutect2, varscan2
- CEP131 | c.21C>T p.I7= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs774470906, COSV99489087; called by muse, varscan2
- COL4A2 | c.1911C>T p.D637= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs764883197, COSV64629199; called by muse, mutect2
- COL5A2 | c.4155T>C p.T1385= | Silent (SNP) | VAF 16/239 reads (7%) | catalogued as COSV100880842; called by muse, mutect2
- COPB1 | c.1557T>G p.G519= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV99999904; called by muse, mutect2
- CSMD2 | c.9783A>T p.P3261= | Silent (SNP) | VAF 38/226 reads (17%) | catalogued as COSV99595596; called by muse, mutect2
- DBX1 | c.417T>C p.F139= | Silent (SNP) | VAF 48/596 reads (8%) | catalogued as COSV99910327; called by muse, mutect2
- DDX49 | c.156G>A p.K52= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV99447876; called by muse, mutect2
- DMBT1 | c.2169G>C p.S723= | Silent (SNP) | VAF 17/300 reads (6%) | catalogued as COSV100354135; called by muse, mutect2
- DNAH7 | c.5857C>T p.L1953= | Silent (SNP) | VAF 11/159 reads (7%) | catalogued as COSV100417675, COSV100417704; called by muse, mutect2
- DOCK10 | c.2463A>G p.Q821= | Silent (SNP) | VAF 9/147 reads (6%) | catalogued as rs1264232143, COSV99291731; called by muse, mutect2
- EVC2 | c.3687C>G p.L1229= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as rs1157926409, COSV60388508, COSV60395141; called by muse, mutect2, varscan2
- FAM117B | c.873G>A p.Q291= | Silent (SNP) | VAF 15/247 reads (6%) | catalogued as COSV100287957; called by muse, mutect2
- FAM120A | c.1632C>T p.T544= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV99466653; called by muse, mutect2
- FAM171B | c.675G>A p.L225= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV100488456, COSV100488805, COSV59001118; called by muse, mutect2, varscan2
- FAM20B | c.21C>T p.V7= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as rs777032848, COSV55379473; called by muse, mutect2, varscan2
- FPR2 | c.417G>A p.V139= | Silent (SNP) | VAF 24/504 reads (5%) | catalogued as COSV100389472; called by muse, mutect2
- GABRG1 | c.75C>T p.F25= | Silent (SNP) | VAF 20/297 reads (7%) | catalogued as COSV99778773; called by muse, mutect2
- GFRA3 | c.591C>G p.L197= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99218558; called by muse, mutect2
- GNPTG | c.630G>A p.R210= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs890055206, COSV50189831; called by muse, mutect2, varscan2
- HTR1E | c.642G>A p.Q214= | Silent (SNP) | VAF 9/234 reads (4%) | catalogued as COSV100541321; called by muse, mutect2
- HUNK | c.1662G>C p.L554= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV99528993; called by muse, mutect2
- KIAA1549 | c.2277C>G p.L759= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as COSV99652086; called by muse, mutect2
- LARS1 | c.3414G>A p.K1138= (on ENST00000394434 / NM_020117.11; = p.K1111= on NM_016460.3) | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV99198880; called by muse, mutect2
- LCK | c.423C>T p.L141= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV60738785; called by muse, mutect2, varscan2
- LIPG | c.1332G>A p.L444= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV54295116; called by muse, mutect2, varscan2
- LMAN2L | c.654C>G p.V218= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV99383645; called by muse, mutect2
- LNX2 | c.810C>T p.V270= | Silent (SNP) | VAF 13/200 reads (7%) | catalogued as COSV100310926; called by muse, mutect2
- METTL4 | c.180T>C p.A60= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV55247112; called by muse, mutect2, varscan2
- MYH13 | c.231C>G p.V77= | Silent (SNP) | VAF 38/563 reads (7%) | catalogued as COSV52849049; called by muse, mutect2
- NEDD4L | c.747C>T p.F249= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV56841047; called by muse, mutect2
- NOS3 | c.1506C>T p.A502= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1204709629, COSV99872190; called by muse, mutect2
- OR10H3 | c.645C>T p.L215= | Silent (SNP) | VAF 38/620 reads (6%) | catalogued as COSV100008527; called by muse, mutect2
- OR51E1 | c.180G>A p.E60= | Silent (SNP) | VAF 24/396 reads (6%) | catalogued as rs1207757548, COSV101211559; called by muse, mutect2
- OSBPL3 | c.1605C>T p.N535= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV57660101; called by muse, mutect2
- PDIA5 | c.861C>T p.D287= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100299761; called by muse, mutect2
- PLD3 | c.996T>G p.T332= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV52519560; called by muse, mutect2, varscan2
- PTCD1 | c.1320C>G p.V440= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99464586; called by muse, mutect2
- RALGAPB | c.3228T>G p.L1076= | Silent (SNP) | VAF 41/194 reads (21%) | catalogued as COSV53434860; called by muse, mutect2, varscan2
- RIN2 | c.2427C>T p.L809= (on ENST00000255006 / NM_001242581.1; = p.L760= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/246 reads (6%) | catalogued as rs989230787, COSV99657932; called by muse, mutect2
- RRAGD | c.747C>T p.N249= | Silent (SNP) | VAF 25/222 reads (11%) | catalogued as rs1306276640, COSV100784653; called by muse, mutect2, varscan2
- SDC3 | c.318G>A p.A106= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs373189918; called by muse, mutect2, varscan2
- SNX30 | c.1158G>C p.L386= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV100953976; called by muse, mutect2
- SPINDOC | c.987G>C p.R329= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV99588800; called by muse, mutect2
- TENM2 | c.3948G>C p.L1316= (on ENST00000518659 / NM_001122679.2; = p.L1077= on NM_001080428.3) | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as COSV101319430; called by muse, mutect2
- TOP1MT | c.1080G>A p.V360= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100239774; called by muse, mutect2
- TPD52 | c.81C>G p.L27= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV100990904; called by muse, mutect2
- TRIM68 | c.315G>A p.L105= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV56167722; called by muse, mutect2, varscan2
- TSC22D3 | c.195G>A p.L65= | Silent (SNP) | VAF 13/196 reads (7%) | catalogued as rs1336050892, COSV100227011, COSV59777336; called by muse, mutect2
- TTC37 | c.912C>G p.V304= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100706914; called by muse, mutect2
- TTN | c.91092C>T p.P30364= (on ENST00000591111; = p.P22940= on NM_003319.4) | Silent (SNP) | VAF 15/138 reads (11%) | catalogued as rs183620684; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- UGT3A1 | c.591C>T p.F197= | Silent (SNP) | VAF 20/482 reads (4%) | catalogued as rs958465777, COSV99955351; called by muse, mutect2
- USH2A | c.3849G>A p.L1283= | Silent (SNP) | VAF 30/239 reads (13%) | catalogued as COSV56333810; called by muse, mutect2, varscan2
- UTP14A | c.1449T>C p.T483= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100929011; called by muse, mutect2
- WDR26 | c.1518T>C p.Y506= (on ENST00000414423 / NM_001379403.1; = p.Y406= on NM_025160.7) | Silent (SNP) | VAF 58/241 reads (24%) | catalogued as rs753632499, COSV54353489; called by muse, mutect2, varscan2
- XRRA1 | c.1623G>C p.L541= | Silent (SNP) | VAF 113/200 reads (57%) | catalogued as COSV100370142; called by muse, mutect2, varscan2
- ZNF14 | c.1320T>C p.T440= | Silent (SNP) | VAF 7/146 reads (5%) | catalogued as COSV100694144; called by muse, mutect2
- ZNF578 | c.972C>T p.F324= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as COSV101405121; called by muse, mutect2
- ZNF611 | c.2025G>A p.E675= | Silent (SNP) | VAF 9/156 reads (6%) | catalogued as COSV100160147, COSV100160627; called by muse, mutect2
- MIR518C | n.28T>C | RNA (SNP) | VAF 13/292 reads (4%) | catalogued as rs1371882524; called by muse, mutect2
- POM121 | chr7:72949912 G>C | 3'Flank (SNP) | VAF 10/134 reads (7%) | catalogued as COSV99989289; called by muse, mutect2
